CCDI case PBBKEA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b0070b60-6b81-40bb-8616-da2db8596033

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, benign: ICD-O-3 morphology code: 8000/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.7 years (2,460 days).

Biospecimens (3 samples)
- Sample 0DAPM8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DAPMB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DAPMC: Tissue type: Tumor; Specimen type: Solid Tissue.
